Gene-level copy-number profile of tumor specimen TCGA-25-2392-01A from TCGA case TCGA-25-2392, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 75.7 years (27,667 days).
Specimen TCGA-25-2392-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ed1cf8c6-d594-49f7-9aa5-9a13cafc0f4a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-2392-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8b0c46ef-12f4-49a5-ae49-9afbb31d1d5a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 100; copy number 1: 768; copy number 2: 5,691; copy number 3: 11,534; copy number 4: 13,557; copy number 5: 11,249; copy number 6: 9,813; copy number 7: 2,803; copy number 8: 1,480; copy number 9: 833; copy number 10: 10; copy number 11: 1,184; copy number 12: 458; copy number 13: 57; copy number 14: 32; copy number 16: 54; copy number 19: 73; copy number 20: 5; copy number 22: 35; copy number 23: 49; copy number 33: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-25-2392-01A-01D-0704-01): tumor purity 0.59, ploidy 4.71, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 100 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,077,104–26,892,803, 83 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:28,598,668–30,990,572, 17 genes: KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,804 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,998,651–160,711,831, 30 genes, copy number 9 (within-gene range 6–9): KCNJ10, AL513302.1, PIGM, AL121987.1, KCNJ9, IGSF8, ATP1A2, ATP1A4, CASQ1, AL121987.2, PEA15, DCAF8, AL139011.2, AL139011.1, RPSAP18, PEX19, COPA, SUMO1P3, Y_RNA, NCSTN, NHLH1, RNU4-42P, VANGL2, SLAMF6, AL138930.1, CD84, SLAMF1, SETP9, AL121985.1, CD48.
- chr2:103,494,241–103,529,261, 2 genes, copy number 9: CRLF3P1, AC018880.1.
- chr2:161,577,192–161,625,752, 1 gene, copy number 13 (within-gene range 5–13): AC062022.2.
- chr8:32,647,202–145,066,685, 1,760 genes, copy number 11–16 (broad region; genes not listed).
- chr9:60,914,407–75,402,992, 262 genes, copy number 9 (broad region; genes not listed).
- chr11:75,758,455–89,498,187, 222 genes, copy number 9–33 (within-gene range 3–33) (broad region; genes not listed).
- chr12:25,409,307–25,648,579, 1 gene, copy number 9 (within-gene range 4–9): LMNTD1.
- chr12:25,585,994–26,125,037, 10 genes, copy number 9: AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41.
- chr12:26,125,155–26,167,741, 2 genes, copy number 9: AC022509.3, AC022509.5.
- chr12:105,019,784–119,877,320, 314 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr13:29,239,379–29,850,617, 6 genes, copy number 9 (within-gene range 5–9): MTUS2-AS2, GAPDHP69, AL596092.1, MTUS2-AS1, SLC7A1, UBL3.
- chr15:60,347,134–61,229,302, 17 genes, copy number 12 (within-gene range 4–12): ANXA2, AC087385.1, AC087385.2, AC087385.3, ICE2, RORA-AS1, RORA, AC107241.1, CYCSP38, AC009560.1, AC009560.3, AC009560.4, AC009560.2, RORA-AS2, RNA5SP397, AC022898.1, AC022898.2.
- chr17:9,250,471–9,576,591, 1 gene, copy number 10 (within-gene range 4–10): STX8.
- chr17:9,452,197–9,729,687, 9 genes, copy number 10: AC087501.1, AC087501.2, AC087501.3, AC087501.4, CFAP52, RPL19P18, AC118755.2, USP43, AC118755.1.
- chr19:37,304,451–40,285,536, 150 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr20:53,453,058–54,651,169, 17 genes, copy number 9 (within-gene range 8–9): AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5.

Autosomal genes at a single copy (total copy number 1): 768. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
